Somatic mutation profile of tumor specimen ALCH-B20F-TTP1-A (aliquot ALCH-B20F-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B20F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.9 years (18,590 days).
Specimen ALCH-B20F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbfe5987-a284-4c86-af11-ed82e5fdb235.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B20F-NB1-A (Blood Derived Normal), aliquot ALCH-B20F-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d9f532-fd1c-40e8-b158-a49d6f8fa44f

The open-access MAF lists 554 somatic variants for this specimen: 393 protein-altering or splice-affecting, 90 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 345, Silent 90, Intron 31, Nonsense Mutation 27, 5'UTR 14, 3'UTR 13, Splice Region 7, RNA 6, Splice Site 5, 3'Flank 4, Frame Shift Del 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 102/916 reads (11%) | catalogued as rs1555484797, COSV52120614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7742G>T p.C2581F | Missense Mutation (SNP) | VAF 54/734 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555394149, CM013942, CM077269; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 32/326 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 62/362 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- A4GNT | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV99367930; called by muse, mutect2
- ACOXL | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100490283; called by muse, mutect2
- ADGRE1 | c.1463C>A p.S488* | Nonsense Mutation (SNP) | VAF 34/460 reads (7%) | catalogued as COSV51678090; called by muse, mutect2
- AFF4 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs956005730, COSV99534439; called by muse, mutect2
- AGRN | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs773144997; ClinVar: uncertain significance; called by muse, mutect2
- ALK | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); catalogued as COSV66571366; called by muse, mutect2, varscan2
- ANO6 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 56/756 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); catalogued as COSV57664233; called by muse, mutect2
- ANPEP | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); catalogued as rs762164247; called by muse, mutect2, varscan2
- BCL9 | c.3271C>T p.Q1091* | Nonsense Mutation (SNP) | VAF 40/908 reads (4%) | catalogued as COSV52347620; called by muse, mutect2
- BEND2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs374044388, COSV66215791, COSV66216816; called by muse, mutect2, varscan2
- C1orf115 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs1443320732, COSV54274510; called by muse, mutect2
- CAD | c.6254G>A p.R2085H | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53023280; called by muse, mutect2
- CALD1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV99054753; called by muse, mutect2
- CAPN9 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 45/838 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as rs753471492; called by muse, mutect2
- CCDC141 | c.3670G>C p.E1224Q | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99836579; called by muse, mutect2
- CCDC178 | c.1961T>A p.L654Q (on ENST00000383096 / NM_001105528.3; = p.L616Q on NM_198995.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV55763879; called by muse, mutect2
- CDH1 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV99932918; called by muse, mutect2
- CDH10 | c.2293C>A p.L765I | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52598784; called by muse, mutect2, varscan2
- CELSR3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 31/539 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV50840456; called by muse, mutect2
- COL1A1 | c.3807G>A p.W1269* | Nonsense Mutation (SNP) | VAF 63/591 reads (11%) | catalogued as CM1411926; called by muse, mutect2, varscan2
- COL22A1 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 70/459 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV57335526; called by muse, mutect2, varscan2
- COL27A1 | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 31/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140917660; called by muse, mutect2
- COL4A2 | c.2947del p.L983Cfs*4 | Frame Shift Del (DEL) | VAF 28/185 reads (15%) | catalogued as COSV64625813; called by mutect2, pindel, varscan2
- CPS1 | c.2571C>T p.A857= | Splice Region (SNP) | VAF 28/742 reads (4%) | catalogued as rs1316902506; called by muse, mutect2
- CR2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as rs1279283315; called by muse, mutect2
- CRHR2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769228837, COSV100529578; called by muse, mutect2, varscan2
- CUL7 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs757682687, COSV99538648; called by muse, mutect2, varscan2
- DCLK2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV56206947; called by muse, mutect2, varscan2
- DMD | c.5040C>A p.H1680Q | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63784209; called by muse, mutect2
- DNAJB8 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs992661568; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2455A>G p.M819V | Missense Mutation (SNP) | VAF 66/507 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1468892329; called by muse, mutect2, varscan2
- EVC | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 64/817 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53830301, COSV53831664; called by muse, mutect2
- EYS | c.2542C>A p.Q848K | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV101012386; called by muse, mutect2, varscan2
- FAM174C | c.399A>G p.*133Wext*2 | Nonstop Mutation (SNP) | VAF 18/272 reads (7%) | catalogued as rs1483412463; called by muse, mutect2
- FAM189A1 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as rs1406580627; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2
- FSCB | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 18/328 reads (5%) | catalogued as COSV61216372; called by muse, mutect2
- GCNT2 | c.1015C>T p.H339Y (on ENST00000379597 / NM_001374747.1; = p.H337Y on NM_001491.3) | Missense Mutation (SNP) | VAF 56/1036 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV53942022; called by muse, mutect2
- GLG1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1239499780; called by muse, mutect2
- GRM6 | c.2299G>T p.V767L | Missense Mutation (SNP) | VAF 25/572 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as COSV51443997; called by muse, mutect2
- HGF | c.1939C>G p.R647G | Missense Mutation (SNP) | VAF 143/796 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55956856; called by muse, mutect2, varscan2
- HK3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 35/453 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52837000; called by muse, mutect2
- HMCN2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs782712196; called by muse, mutect2, varscan2
- HNRNPUL2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 40/614 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV53665903, COSV53666016; called by muse, mutect2
- HP1BP3 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 42/438 reads (10%) | catalogued as COSV56561250, COSV56564032; called by muse, mutect2
- HSD3B7 | c.531+3G>A | Splice Region (SNP) | VAF 46/712 reads (6%) | catalogued as rs894869356; called by muse, mutect2
- HTT | c.9401G>A p.R3134Q | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374128370; called by muse, mutect2
- ITGAD | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 32/924 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1427548176, COSV54931609; called by muse, mutect2
- KAT6A | c.4627C>G p.Q1543E | Missense Mutation (SNP) | VAF 34/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55902670, COSV99705454; called by muse, mutect2
- KCNJ8 | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 76/786 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV53715303; called by muse, mutect2
- KCNK18 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100572143; called by muse, mutect2
- KCNQ3 | c.1657G>T p.G553W | Missense Mutation (SNP) | VAF 55/896 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464164, COSV66476011; called by muse, mutect2
- LAMA4 | c.1141G>A p.A381T (on ENST00000230538 / NM_001105206.3; = p.A374T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/640 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs141633339; called by muse, mutect2
- LDB2 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV100455343; called by muse, mutect2, varscan2
- LIX1L | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 26/810 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1553757829; called by muse, mutect2
- LRBA | c.3992A>G p.Q1331R | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1334258849, COSV63966641; called by muse, mutect2
- LRRC31 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1355241684; called by muse, mutect2, varscan2
- LRRK2 | c.5120G>T p.R1707I | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100111062; called by muse, mutect2, varscan2
- MACC1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs915948986; called by muse, mutect2
- MACF1 | c.6454G>A p.D2152N | Missense Mutation (SNP) | VAF 13/191 reads (7%) | catalogued as rs1245358186, COSV99243992; called by muse, mutect2
- MAG | c.1396A>G p.S466G | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1376077841; called by muse, mutect2, varscan2
- MAP2 | c.4431G>T p.Q1477H | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99558199; called by muse, mutect2
- MAP6 | c.1687G>C p.G563R | Missense Mutation (SNP) | VAF 46/442 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs750534536, COSV59074387; called by muse, mutect2
- MTSS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 60/975 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs767819646; called by muse, mutect2
- MYH2 | c.4941G>T p.R1647S | Missense Mutation (SNP) | VAF 34/786 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV55432633; called by muse, mutect2
- MYO9B | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.363); catalogued as COSV101261208, COSV68282552; called by muse, mutect2, varscan2
- NDUFA3 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99499791; called by muse, mutect2
- NKAPL | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as COSV59199744; called by muse, mutect2
- NLRP13 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 63/441 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1171946395, COSV100738191; called by muse, mutect2, varscan2
- NLRP4 | c.1125C>G p.F375L | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs373243158, COSV56710515; called by muse, mutect2
- NXN | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61099340; called by muse, mutect2, varscan2
- OR10G9 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV66686209; called by muse, mutect2
- OR5L2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV65723841; called by muse, mutect2, varscan2
- OR8K3 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as rs749422741; called by muse, mutect2, varscan2
- ORAI1 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 61/484 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100345523; called by muse, mutect2, varscan2
- PCDHB13 | c.1917G>T p.R639S | Missense Mutation (SNP) | VAF 35/1130 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV53395441; called by muse, mutect2
- PCDHB7 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1554280024, COSV50770160; called by muse, mutect2, varscan2
- PCLO | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1428811438, COSV61615815, COSV61644737; called by muse, mutect2
- PFKFB1 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 16/244 reads (7%) | catalogued as COSV100895662; called by muse, mutect2
- PFKFB4 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 19/181 reads (10%) | PolyPhen probably damaging (0.997); catalogued as rs779691575; called by muse, mutect2, varscan2
- PGK2 | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV59163737; called by muse, mutect2
- PGM1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 36/741 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64301012; called by muse, mutect2
- PITPNM3 | c.467C>G p.T156S | Missense Mutation (SNP) | VAF 51/845 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs760504894; called by muse, mutect2
- PLCE1 | c.4153G>C p.D1385H | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99595841; called by muse, mutect2
- PLCH1 | c.4039G>A p.D1347N (on ENST00000340059 / NM_001130960.2; = p.D1339N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/601 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58194289; called by muse, mutect2
- PLEC | c.1345G>A p.E449K (on ENST00000322810 / NM_201380.4; = p.E339K on NM_000445.5) | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs577853547, COSV59647824; ClinVar: uncertain significance; called by muse, mutect2
- PLIN5 | c.1063C>A p.H355N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV67850378; called by muse, mutect2
- PLPPR4 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200541722, COSV64565487, COSV64567434; called by muse, mutect2
- PLXDC2 | c.1010G>T p.C337F | Missense Mutation (SNP) | VAF 66/764 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV65907166; called by muse, mutect2
- PLXNA3 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1557207521; called by muse, mutect2, varscan2
- PRKCB | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); catalogued as COSV57764040; called by muse, mutect2, varscan2
- PSG3 | c.622A>T p.T208S | Missense Mutation (SNP) | VAF 47/558 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59503268; called by muse, mutect2
- PTK7 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as rs1314278254; called by muse, mutect2
- PTPRD | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV61962282; called by muse, mutect2, varscan2
- PTPRQ | c.2447G>C p.G816A (on ENST00000616559; = p.G774A on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.209); catalogued as COSV57034624; called by muse, mutect2
- QSER1 | c.962C>T p.S321L (on ENST00000399302; = p.S450L on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs757717317, COSV67902041; called by muse, mutect2
- RBM4 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1173767967, COSV59519688; called by muse, mutect2
- RETREG3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1308800913, COSV52222064; called by muse, mutect2
- RHBDD3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53323433; called by muse, mutect2, varscan2
- RNF103 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 12/345 reads (3%) | catalogued as COSV99410134; called by muse, mutect2
- RP1L1 | c.3491G>C p.G1164A | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs1401566962, COSV66759750; called by muse, mutect2, varscan2
- RRH | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 33/676 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV58491656; called by muse, mutect2
- SCN5A | c.4913G>A p.R1638Q (on ENST00000333535 / NM_198056.3; = p.R1637Q on NM_000335.5) | Missense Mutation (SNP) | VAF 63/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374557801, COSV61123571; called by muse, mutect2, varscan2
- SEM1 | c.200C>G p.A67G | Missense Mutation (SNP) | VAF 64/695 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.269); catalogued as COSV63135064; called by muse, mutect2
- SEMA5B | c.2560G>C p.G854R | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52092170; called by muse, mutect2, varscan2
- SETDB2 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV99320788; called by muse, mutect2, varscan2
- SHCBP1L | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 31/389 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.273); catalogued as rs1422995984; called by muse, mutect2
- SIPA1L3 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.104); catalogued as rs1391530983; called by muse, mutect2
- SLC25A13 | c.1583C>G p.A528G | Missense Mutation (SNP) | VAF 60/695 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV99673061; called by muse, mutect2
- SLC35E1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs989936448; called by muse, mutect2
- SLC41A3 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 48/919 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59990656; called by muse, mutect2
- SLC4A7 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 84/630 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376495110; called by muse, mutect2, varscan2
- SLC6A16 | c.2078del p.G693Efs*5 | Frame Shift Del (DEL) | VAF 81/647 reads (13%) | catalogued as COSV60028291; called by mutect2, pindel, varscan2
- SOX6 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 135/976 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57038526; called by muse, mutect2, varscan2
- SPEG | c.9187G>C p.A3063P | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV56668731; called by muse, mutect2
- ST6GALNAC4 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 32/286 reads (11%) | PolyPhen probably damaging (0.969); catalogued as rs760422008, COSV100231571, COSV59129759; called by muse, mutect2, varscan2
- STAG2 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV54354995; called by muse, mutect2, varscan2
- TCOF1 | c.1918C>G p.Q640E (on ENST00000377797 / NM_001135243.1; = p.Q563E on NM_000356.4) | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM042791; called by muse, mutect2
- TMC5 | c.2990G>C p.R997T (on ENST00000396229 / NM_001105248.1; = p.R751T on NM_024780.5) | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1228929486; called by muse, mutect2
- TMEM132A | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV50003314; called by muse, mutect2
- TMEM196 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV68254856; called by muse, mutect2
- TNNI3 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1201960520; called by muse, mutect2
- TNRC6A | c.3592G>C p.E1198Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV59360236; called by muse, mutect2
- TOPBP1 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV53432410; called by muse, varscan2
- TRIM27 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs1446022629; called by muse, mutect2
- TRIM62 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV99357823; called by muse, mutect2
- TTN | c.12793G>A p.E4265K (on ENST00000591111; = p.E4219K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/368 reads (5%) | catalogued as COSV60301205; called by muse, mutect2
- TTN | c.4448G>C p.R1483T (on ENST00000591111; = p.R1437T on NM_003319.4) | Missense Mutation (SNP) | VAF 30/250 reads (12%) | PolyPhen benign (0.322); catalogued as COSV100635573; called by muse, mutect2, varscan2
- UGP2 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.414); catalogued as COSV100451594; called by muse, mutect2
- UGT1A8 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 21/473 reads (4%) | catalogued as COSV65081488; called by muse, mutect2
- USH1C | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 60/924 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50014471; called by muse, mutect2
- USH2A | c.5774C>T p.T1925I | Missense Mutation (SNP) | VAF 52/597 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100238337; called by muse, mutect2
- USP29 | c.1857G>T p.Q619H | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV54143502; called by muse, mutect2
- USP31 | c.3865G>T p.G1289* | Nonsense Mutation (SNP) | VAF 38/251 reads (15%) | catalogued as COSV54849511, COSV54857119; called by muse, mutect2, varscan2
- VIT | c.1523C>A p.T508K (on ENST00000389975 / NM_001177969.1; = p.T523K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV101007796, COSV99061748; called by muse, mutect2, varscan2
- VWCE | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57114540; called by muse, mutect2
- WDR48 | c.48+6G>A | Splice Region (SNP) | VAF 21/460 reads (5%) | catalogued as rs1387758097, COSV100176337; called by muse, mutect2
- ZBBX | c.2235G>C p.K745N | Missense Mutation (SNP) | VAF 55/432 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1317664956, COSV100283289; called by muse, mutect2, varscan2
- ZBTB38 | c.2309G>T p.R770I | Missense Mutation (SNP) | VAF 76/562 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV58542221; called by muse, varscan2
- ZC3H3 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226132852, COSV52789269; called by muse, mutect2
- ZFP28 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs1450063629; called by muse, mutect2
- ZIC1 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51558391; called by muse, mutect2
- ZNF239 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 39/483 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV60017953; called by muse, mutect2
- ZNF619 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 36/232 reads (16%) | catalogued as COSV59030062; called by muse, varscan2
- ZNF622 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100433080; called by muse, mutect2
- ADAMTS18 | c.1841G>C p.R614T | Missense Mutation (SNP) | VAF 34/1138 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS2 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY7 | c.2221C>G p.L741V | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- ADGRF3 | c.1951G>C p.E651Q (on ENST00000311519 / NM_001145168.1; = p.E452Q on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/946 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.348); called by muse, mutect2
- ADGRF5 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 77/558 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG2 | c.329G>T p.C110F (on ENST00000379869 / NM_001079858.3; = p.C107F on NM_005756.4) | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- ADRA1A | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- AL121899.2 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 41/570 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- AL592490.1 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 88/595 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ALDH8A1 | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- ALMS1 | c.3647A>G p.Q1216R | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2
- ALS2 | c.3382C>G p.Q1128E | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ANKRD42 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- ANKS3 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- ARHGEF1 | c.533G>C p.W178S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); called by muse, mutect2
- ARHGEF15 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ARHGEF28 | c.5071G>A p.D1691N (on ENST00000426542; = p.D1717N on NM_001080479.2) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2
- ARHGEF9 | c.979T>A p.W327R | Missense Mutation (SNP) | VAF 21/509 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ASAP1 | c.3014G>C p.G1005A | Missense Mutation (SNP) | VAF 20/544 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- ASCC3 | c.5728G>A p.D1910N | Missense Mutation (SNP) | VAF 39/604 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- ATP8B2 | c.1462G>C p.E488Q (on ENST00000672630; = p.E455Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- AZGP1 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- BANK1 | c.2149-8A>G | Splice Region (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- BCL9 | c.3917C>A p.T1306K | Missense Mutation (SNP) | VAF 54/566 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, mutect2
- C11orf24 | c.486G>C p.M162I | Missense Mutation (SNP) | VAF 34/648 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- CADPS2 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC181 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 84/523 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPG | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- CDH12 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDKL2 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CEACAM8 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 92/822 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CENPC | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP170B | c.2542C>T p.Q848* (on ENST00000453495; = p.Q777* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- CEP192 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFAP54 | c.6148C>G p.Q2050E | Missense Mutation (SNP) | VAF 53/694 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2
- CMYA5 | c.1812G>C p.L604F | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- CNOT4 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 17/515 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- COLGALT2 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 26/842 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COPS7A | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 29/422 reads (7%) | called by muse, mutect2
- CPNE4 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CRB2 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2
- CSMD3 | c.7452T>A p.C2484* (on ENST00000297405 / NM_001363185.1; = p.C2380* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 32/870 reads (4%) | called by muse, mutect2
- CSMD3 | c.3339T>A p.H1113Q (on ENST00000297405 / NM_001363185.1; = p.H1009Q on NM_052900.3) | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); called by muse, mutect2
- CSN2 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- DCAF1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.157); called by muse, mutect2
- DCD | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.937); called by muse, mutect2
- DDX58 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB125 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); called by muse, mutect2
- DHX38 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- DISP2 | c.1584C>G p.F528L | Missense Mutation (SNP) | VAF 36/622 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- DLG2 | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 94/826 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DLGAP1 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 38/874 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2
- DLL1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- DMXL1 | c.6304G>A p.D2102N | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- DNAH12 | c.3094G>C p.E1032Q (on ENST00000351747; = p.E1055Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2
- DNAH6 | c.11323G>A p.E3775K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAH7 | c.6446C>A p.T2149N | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); called by muse, mutect2
- DOCK4 | c.969A>T p.K323N | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DYNC1I2 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.119); called by muse, mutect2
- DYNC2H1 | c.3125C>G p.S1042* | Nonsense Mutation (SNP) | VAF 19/198 reads (10%) | called by muse, mutect2
- EFHC1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 21/505 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ELMOD1 | c.17+2T>A p.X6_splice | Splice Site (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- EPOP | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERCC6 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 48/775 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.265); called by muse, mutect2
- ERICH3 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVI5L | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM160A1 | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM160A1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 37/401 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2
- FAM185A | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 90/604 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- FKBP6 | c.413A>T p.E138V | Missense Mutation (SNP) | VAF 197/884 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FKBP9 | c.860del p.G287Afs*28 | Frame Shift Del (DEL) | VAF 40/200 reads (20%) | called by mutect2, varscan2
- FOXI1 | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 30/1078 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2
- FSHR | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2
- FSIP2 | c.5414C>G p.S1805C | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GK2 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GLG1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 28/227 reads (12%) | called by muse, mutect2, varscan2
- GLYAT | c.55A>T p.R19W | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- GPR149 | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 97/399 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- GPR174 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 36/336 reads (11%) | called by muse, mutect2, varscan2
- GRIK5 | c.2171C>A p.T724N | Missense Mutation (SNP) | VAF 62/677 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIP1 | c.2420A>T p.D807V (on ENST00000359742 / NM_001379345.1; = p.D755V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- GRN | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- HAO2 | c.772-1G>C p.X258_splice | Splice Site (SNP) | VAF 21/329 reads (6%) | called by muse, mutect2
- HCN2 | c.1266G>C p.M422I | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- HEPHL1 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 83/665 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD10 | c.685A>T p.R229W | Missense Mutation (SNP) | VAF 80/834 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- HSPA6 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 74/921 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- HSPG2 | c.8224G>C p.E2742Q | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- IFNL1 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- IGKV1-16 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 224/1343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGKV1-6 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 137/1066 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGSF1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 94/842 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- INA | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- INSM1 | c.341A>T p.K114M | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2
- INSR | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IRF2BP1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- KATNAL1 | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KBTBD11 | c.1067T>G p.V356G | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KCNC3 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- KCNH5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 26/706 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); called by muse, mutect2
- KCNQ4 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2
- KIAA0753 | c.1599A>T p.R533S | Missense Mutation (SNP) | VAF 89/572 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA0825 | c.2870G>A p.R957K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- KLC1 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- KLHL4 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2
- LAS1L | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.437); called by muse, mutect2
- LEMD3 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LILRA2 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- LMO7 | c.3061-2A>T p.X1021_splice (on ENST00000357063; = p.X702_splice on NM_005358.5) | Splice Site (SNP) | VAF 41/402 reads (10%) | called by muse, mutect2
- LRCH2 | c.2222T>A p.L741H | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC66 | c.954G>C p.R318S | Missense Mutation (SNP) | VAF 60/643 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2
- LRRN1 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- MAGEB18 | c.667A>C p.M223L | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCO | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 150/742 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MCCC1 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 206/1081 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKI67 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2
- MMS19 | c.1321A>T p.K441* | Nonsense Mutation (SNP) | VAF 28/531 reads (5%) | called by muse, mutect2
- MRC1 | c.3519G>C p.R1173S | Missense Mutation (SNP) | VAF 98/882 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2B | c.1619T>A p.I540K | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MS4A4A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 150/530 reads (28%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, varscan2
- MSN | c.1684A>T p.I562F | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTHFR | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS1 | c.1628C>G p.S543* | Nonsense Mutation (SNP) | VAF 36/516 reads (7%) | called by muse, mutect2
- MUC16 | c.20192C>G p.S6731* | Nonsense Mutation (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- MYH15 | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 51/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO16 | c.4165C>A p.P1389T | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- MYO3B | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAM2 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NCKAP5L | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.10193C>G p.P3398R | Missense Mutation (SNP) | VAF 104/814 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECTIN1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 49/1073 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.156); called by muse, mutect2
- NEK7 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 51/882 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2
- NEUROD1 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 78/824 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NIN | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 17/383 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- NLRP3 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NPAS3 | c.1555A>T p.S519C (on ENST00000356141 / NM_001164749.2; = p.S487C on NM_022123.3) | Missense Mutation (SNP) | VAF 28/672 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NRDC | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- NRXN1 | c.3546+1G>T p.X1182_splice | Splice Site (SNP) | VAF 71/463 reads (15%) | called by muse, mutect2, varscan2
- NTM | c.510A>T p.R170S | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- NUDC | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 26/473 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2
- NUTM1 | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 91/789 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR13C3 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR13C3 | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- OR14I1 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5B21 | c.59dup p.N20Kfs*44 | Frame Shift Ins (INS) | VAF 31/280 reads (11%) | called by mutect2, pindel, varscan2
- OR5L1 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- OSBPL6 | c.2621G>C p.R874T | Missense Mutation (SNP) | VAF 20/559 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2
- OTOA | c.902C>G p.T301R | Missense Mutation (SNP) | VAF 68/673 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD4 | c.2398C>G p.Q800E (on ENST00000447906 / NM_001366057.1; = p.Q735E on NM_001102653.1) | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by muse, mutect2
- P3H1 | c.1878C>G p.N626K | Missense Mutation (SNP) | VAF 46/810 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.09); called by muse, mutect2
- PABPC4L | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 86/870 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAK3 | c.1044G>T p.L348F (on ENST00000262836 / NM_001324328.2; = p.L333F on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/728 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- PAPPA2 | c.3049G>T p.V1017L | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PARP11 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH11X | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 126/1105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA8 | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- PCNT | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 88/490 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX2 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 39/656 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.114); called by muse, mutect2
- PDIA2 | c.374_389del p.N125Tfs*38 | Frame Shift Del (DEL) | VAF 37/418 reads (9%) | called by mutect2, pindel
- PHF21A | c.1620A>C p.E540D (on ENST00000418153 / NM_001101802.3; = p.E494D on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.141); called by muse, varscan2
- PIGO | c.3175A>T p.S1059C | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PLA2G4A | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHH2 | c.2594G>C p.R865T | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- POLR2C | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); called by muse, mutect2
- POLR3A | c.3897A>C p.E1299D | Missense Mutation (SNP) | VAF 97/754 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3C | c.719A>C p.D240A | Missense Mutation (SNP) | VAF 92/618 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2
- PPP4R4 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- PRKRIP1 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 49/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRLR | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PROM2 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 15/483 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRPS1L1 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2
- PRR23A | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.911); called by muse, mutect2
- PRR32 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 67/824 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.403); called by muse, mutect2
- PSAPL1 | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.367); called by muse, mutect2
- PYGM | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- QSER1 | c.1169A>G p.Q390R (on ENST00000399302; = p.Q519R on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- R3HDM1 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPH1 | c.3185T>C p.V1062A | Missense Mutation (SNP) | VAF 20/551 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- RBBP7 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RELN | c.8815A>T p.T2939S | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RIMBP2 | c.2500G>C p.D834H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- RNF111 | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2
- RPAP3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 33/494 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- RRAGA | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 40/345 reads (12%) | called by muse, mutect2, varscan2
- RTN3 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 27/514 reads (5%) | called by muse, mutect2
- SAAL1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAGE1 | c.1824G>T p.M608I | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- SARAF | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SELP | c.481+2T>A p.X161_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2
- SEMA3E | c.1588T>A p.C530S | Missense Mutation (SNP) | VAF 38/877 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SERPINA10 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 28/580 reads (5%) | called by muse, mutect2
- SEZ6L | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SFTPB | c.195C>A p.A65= | Splice Region (SNP) | VAF 30/594 reads (5%) | called by muse, mutect2
- SGSH | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIX5 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- SLC15A4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2
- SLC2A14 | c.1140G>C p.K380N | Missense Mutation (SNP) | VAF 113/590 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SLC4A1 | c.2657T>A p.L886Q | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- SLC5A5 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 84/924 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SPAST | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPIB | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SRA1 | c.62-6C>G | Splice Region (SNP) | VAF 33/405 reads (8%) | called by muse, mutect2
- SRBD1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 30/1003 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); called by muse, mutect2
- ST6GAL2 | c.1407C>A p.H469Q | Missense Mutation (SNP) | VAF 54/686 reads (8%) | PolyPhen probably damaging (0.988); called by muse, mutect2
- STK3 | c.1388T>A p.I463K | Missense Mutation (SNP) | VAF 40/820 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TADA3 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.477); called by muse, mutect2
- TBK1 | c.2067-5A>G | Splice Region (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- TENM2 | c.3138G>C p.Q1046H (on ENST00000518659 / NM_001122679.2; = p.Q814H on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- TLE1 | c.998C>G p.A333G | Missense Mutation (SNP) | VAF 98/664 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN2 | c.3371G>A p.R1124K | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TMLHE | c.968dup p.W324Mfs*3 | Frame Shift Ins (INS) | VAF 42/378 reads (11%) | called by mutect2, pindel, varscan2
- TNRC18 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- TOM1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 23/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF4 | c.276G>C p.W92C | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRMT61B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- TRMT9B | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- TSPAN7 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTC17 | c.2417G>C p.G806A | Missense Mutation (SNP) | VAF 21/413 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.43651G>C p.V14551L (on ENST00000591111; = p.V7127L on NM_003319.4) | Missense Mutation (SNP) | VAF 48/544 reads (9%) | PolyPhen possibly damaging (0.629); called by muse, mutect2
- TTN | c.29992G>A p.E9998K (on ENST00000591111; = p.E9071K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/549 reads (6%) | PolyPhen benign (0.055); called by muse, mutect2
- UBR5 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- UBTF | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.068); called by muse, mutect2
- ULK1 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2
- UMODL1 | c.746_760del p.D249_R253del | In Frame Del (DEL) | VAF 27/203 reads (13%) | called by mutect2, pindel
- USH2A | c.14729T>A p.V4910E | Missense Mutation (SNP) | VAF 40/645 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2
- XIRP2 | c.6934G>C p.D2312H (on ENST00000628543; = p.D2487H on NM_152381.6) | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- XKR3 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 64/852 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- YIPF6 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZBTB32 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.096); called by muse, mutect2
- ZDBF2 | c.5147C>G p.S1716C | Missense Mutation (SNP) | VAF 56/559 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by mutect2, varscan2
- ZFHX3 | c.6001C>T p.H2001Y | Missense Mutation (SNP) | VAF 62/670 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZFP62 | c.2660G>A p.G887E (on ENST00000502412 / NM_001377944.1; = p.G854E on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- ZNF343 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2
- ZNF423 | c.1066C>T p.P356S (on ENST00000563137 / NM_001379286.1; = p.P348S on NM_015069.4) | Missense Mutation (SNP) | VAF 48/834 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); called by muse, mutect2
- ZNF429 | c.870T>A p.C290* | Nonsense Mutation (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- ZNF462 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF469 | c.9571G>A p.E3191K (on ENST00000437464; = p.E3219K on NM_001367624.2) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ZNF534 | c.1577G>A p.R526K (on ENST00000332323 / NM_001143939.3; = p.R513K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.216); called by muse, mutect2
- ZNF544 | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ZNF547 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF672 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF708 | c.889A>T p.N297Y | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); called by muse, mutect2
- ZNF75D | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 40/505 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ZNF888 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 28/797 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCD4 | c.495C>T p.I165= | Silent (SNP) | VAF 25/608 reads (4%) | called by muse, mutect2
- AC099489.1 | c.4413G>A p.L1471= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs960437799; called by muse, mutect2
- ACSS1 | c.1860C>T p.I620= | Silent (SNP) | VAF 49/402 reads (12%) | catalogued as rs1313152557, COSV60219907; called by muse, mutect2, varscan2
- ADGRE2 | c.621T>C p.N207= | Silent (SNP) | VAF 44/368 reads (12%) | catalogued as rs1232186242, COSV59693379; called by muse, varscan2
- ADGRG1 | c.51C>T p.L17= | Silent (SNP) | VAF 79/668 reads (12%) | catalogued as rs752783011; called by muse, mutect2, varscan2
- ANO4 | c.100C>T p.L34= | Silent (SNP) | VAF 15/394 reads (4%) | called by muse, mutect2
- ARFGEF3 | c.4995C>T p.A1665= | Silent (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
- ASAP1 | c.3216G>A p.V1072= | Silent (SNP) | VAF 13/287 reads (5%) | catalogued as rs1014044964; called by muse, mutect2
- ASB9 | c.549C>G p.V183= | Silent (SNP) | VAF 44/337 reads (13%) | called by muse, varscan2
- ASPM | c.5541G>C p.V1847= | Silent (SNP) | VAF 24/419 reads (6%) | called by muse, mutect2
- ATP6V0A4 | c.900G>A p.Q300= | Silent (SNP) | VAF 94/1242 reads (8%) | called by muse, mutect2
- BHMG1 | c.135A>T p.G45= | Silent (SNP) | VAF 76/608 reads (13%) | called by muse, varscan2
- BRINP3 | c.577C>A p.R193= | Silent (SNP) | VAF 24/620 reads (4%) | catalogued as rs1469434553, COSV66527593; called by muse, mutect2
- C14orf180 | c.198G>C p.S66= | Silent (SNP) | VAF 9/214 reads (4%) | catalogued as rs748580951, COSV59557867; called by muse, mutect2
- C19orf71 | c.435G>A p.R145= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100281270; called by muse, mutect2, varscan2
- CBLN2 | c.105G>T p.A35= | Silent (SNP) | VAF 14/179 reads (8%) | catalogued as COSV54052200; called by muse, mutect2
- CDAN1 | c.117G>C p.L39= | Silent (SNP) | VAF 21/574 reads (4%) | called by muse, mutect2
- CHD6 | c.4518C>T p.C1506= | Silent (SNP) | VAF 86/568 reads (15%) | called by muse, mutect2, varscan2
- CLOCK | c.381A>T p.T127= | Silent (SNP) | VAF 29/240 reads (12%) | called by muse, mutect2, varscan2
- CNTN5 | c.1743A>G p.T581= | Silent (SNP) | VAF 42/226 reads (19%) | called by muse, mutect2
- CRIM1 | c.579G>A p.L193= | Silent (SNP) | VAF 35/825 reads (4%) | called by muse, mutect2
- CRYBG2 | c.3525C>T p.A1175= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as rs1423889034; called by muse, mutect2
- DAAM1 | c.721C>T p.L241= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs980120198, COSV62835459; called by muse, mutect2
- DDX46 | c.606C>T p.D202= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs759439661, COSV62800050; called by muse, mutect2, varscan2
- DNAH5 | c.12162C>T p.D4054= | Silent (SNP) | VAF 38/912 reads (4%) | called by muse, mutect2
- DNAH8 | c.7179C>A p.T2393= | Silent (SNP) | VAF 21/412 reads (5%) | catalogued as COSV100543688, COSV100544422; called by muse, mutect2
- DNAI2 | c.339C>G p.L113= | Silent (SNP) | VAF 16/484 reads (3%) | catalogued as rs957243389; called by muse, mutect2
- ESRRB | c.1254A>G p.K418= | Silent (SNP) | VAF 83/542 reads (15%) | called by muse, mutect2, varscan2
- FAM76B | c.873G>A p.L291= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- FARP2 | c.1737C>T p.L579= | Silent (SNP) | VAF 37/363 reads (10%) | catalogued as rs1361417917, COSV50874900; called by muse, mutect2, varscan2
- FLG | c.1407C>G p.L469= | Silent (SNP) | VAF 52/746 reads (7%) | called by muse, mutect2
- FOXJ1 | c.360G>A p.V120= | Silent (SNP) | VAF 23/451 reads (5%) | catalogued as COSV99487472; called by muse, mutect2
- GUCY2C | c.1143T>A p.L381= | Silent (SNP) | VAF 46/429 reads (11%) | called by muse, mutect2, varscan2
- GYPE | c.42T>A p.I14= | Silent (SNP) | VAF 32/904 reads (4%) | called by muse, mutect2
- HAPLN2 | c.763C>A p.R255= | Silent (SNP) | VAF 21/622 reads (3%) | called by muse, mutect2
- HARS2 | c.495C>T p.V165= | Silent (SNP) | VAF 70/1308 reads (5%) | called by muse, mutect2
- HERC2 | c.222A>G p.E74= | Silent (SNP) | VAF 12/375 reads (3%) | called by muse, mutect2
- HGFAC | c.1287C>T p.D429= | Silent (SNP) | VAF 45/350 reads (13%) | catalogued as rs773253102; called by muse, mutect2, varscan2
- ICAM5 | c.441C>T p.A147= | Silent (SNP) | VAF 33/599 reads (6%) | catalogued as rs770864531; called by muse, mutect2
- INHA | c.135G>C p.A45= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as COSV54728383, COSV99217195; called by muse, mutect2
- INTS3 | c.462G>A p.K154= | Silent (SNP) | VAF 48/980 reads (5%) | called by muse, mutect2
- INTS3 | c.2898C>T p.F966= | Silent (SNP) | VAF 36/347 reads (10%) | catalogued as rs1442010766; called by muse, mutect2
- ITGA7 | c.2691C>T p.L897= (on ENST00000555728; = p.L853= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/851 reads (4%) | catalogued as COSV57695089; called by muse, mutect2
- KCTD5 | c.210G>A p.L70= | Silent (SNP) | VAF 59/558 reads (11%) | called by muse, mutect2, varscan2
- KRTAP5-6 | c.261G>A p.Q87= | Silent (SNP) | VAF 42/906 reads (5%) | called by muse, mutect2
- LAS1L | c.852G>A p.L284= | Silent (SNP) | VAF 38/343 reads (11%) | called by muse, mutect2
- LIG1 | c.2547C>T p.L849= | Silent (SNP) | VAF 31/590 reads (5%) | catalogued as COSV54392647; called by muse, mutect2
- LRRC9 | c.2025A>G p.K675= | Silent (SNP) | VAF 18/482 reads (4%) | called by muse, mutect2
- LSG1 | c.921T>C p.Y307= | Silent (SNP) | VAF 78/491 reads (16%) | called by muse, mutect2, varscan2
- MAGEL2 | c.774G>T p.P258= | Silent (SNP) | VAF 28/293 reads (10%) | catalogued as COSV58566466; called by muse, mutect2
- MAP3K2 | c.1782C>G p.L594= | Silent (SNP) | VAF 75/727 reads (10%) | called by muse, mutect2, varscan2
- MRPL18 | c.291G>A p.Q97= | Silent (SNP) | VAF 42/736 reads (6%) | called by muse, mutect2
- MST1R | c.1314A>G p.L438= | Silent (SNP) | VAF 29/654 reads (4%) | called by muse, mutect2
- MYH8 | c.618G>A p.E206= | Silent (SNP) | VAF 56/932 reads (6%) | called by muse, mutect2
- NCOR2 | c.5604C>T p.L1868= | Silent (SNP) | VAF 24/518 reads (5%) | catalogued as COSV62299946, COSV62301613; called by muse, mutect2
- NKAPL | c.141C>A p.G47= | Silent (SNP) | VAF 19/341 reads (6%) | called by muse, mutect2
- NPB | c.369C>T p.L123= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100325929, COSV58711500; called by muse, mutect2, varscan2
- OPN3 | c.1092G>A p.V364= | Silent (SNP) | VAF 32/628 reads (5%) | called by muse, mutect2
- OR10Q1 | c.414C>T p.L138= | Silent (SNP) | VAF 15/300 reads (5%) | called by muse, mutect2
- OR51L1 | c.105T>C p.L35= | Silent (SNP) | VAF 22/480 reads (5%) | called by muse, mutect2
- OR52E4 | c.429C>A p.I143= | Silent (SNP) | VAF 58/356 reads (16%) | catalogued as COSV57625681; called by muse, mutect2, varscan2
- OR56A3 | c.255C>A p.V85= | Silent (SNP) | VAF 44/684 reads (6%) | called by muse, mutect2
- PAK1 | c.354G>A p.K118= | Silent (SNP) | VAF 38/305 reads (12%) | catalogued as COSV53697667; called by muse, mutect2, varscan2
- PPARGC1B | c.57C>G p.L19= | Silent (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- PROP1 | c.99C>A p.T33= | Silent (SNP) | VAF 189/648 reads (29%) | called by muse, mutect2, varscan2
- PRPF3 | c.189G>T p.V63= | Silent (SNP) | VAF 86/985 reads (9%) | called by muse, mutect2
- PRPF39 | c.165A>C p.T55= | Silent (SNP) | VAF 79/524 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.8469C>A p.P2823= | Silent (SNP) | VAF 34/948 reads (4%) | called by muse, mutect2
- S1PR1 | c.873C>T p.F291= | Silent (SNP) | VAF 28/492 reads (6%) | catalogued as COSV59513477; called by muse, mutect2
- SAAL1 | c.675G>T p.G225= | Silent (SNP) | VAF 45/444 reads (10%) | called by muse, mutect2, varscan2
- SCN3A | c.612A>G p.T204= | Silent (SNP) | VAF 47/1225 reads (4%) | called by muse, mutect2
- SCNN1A | c.744G>C p.V248= | Silent (SNP) | VAF 84/880 reads (10%) | called by muse, mutect2
- SH3GL3 | c.630A>G p.E210= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- SI | c.3856A>C p.R1286= | Silent (SNP) | VAF 22/572 reads (4%) | catalogued as COSV100015694; called by muse, mutect2
- SLC4A2 | c.2211G>C p.L737= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV52540264, COSV99879743; called by muse, mutect2, varscan2
- SLC4A9 | c.555C>A p.T185= (on ENST00000507527 / NM_001258428.2; = p.T161= on NM_031467.3) | Silent (SNP) | VAF 103/366 reads (28%) | catalogued as rs1193850651; called by muse, mutect2, varscan2
- SMR3B | c.30T>G p.L10= | Silent (SNP) | VAF 37/466 reads (8%) | called by muse, mutect2
- SPATA16 | c.1407G>A p.Q469= | Silent (SNP) | VAF 217/1094 reads (20%) | catalogued as rs1360956555; called by muse, mutect2, varscan2
- SPATA16 | c.555T>C p.S185= | Silent (SNP) | VAF 210/1009 reads (21%) | called by muse, mutect2, varscan2
- SSU72P8 | c.411C>T p.I137= | Silent (SNP) | VAF 66/325 reads (20%) | called by muse, mutect2, varscan2
- TAS2R31 | c.414A>G p.L138= | Silent (SNP) | VAF 21/344 reads (6%) | catalogued as rs748791918; called by muse, mutect2
- TEDC1 | c.1119G>T p.R373= (on ENST00000392523 / NM_001367178.1; = p.R304= on NM_001134875.1) | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- TEX15 | c.3807A>C p.S1269= (on ENST00000256246; = p.S1652= on NM_001350162.2) | Silent (SNP) | VAF 36/380 reads (9%) | called by muse, mutect2
- TIMP3 | c.171C>T p.F57= | Silent (SNP) | VAF 60/836 reads (7%) | catalogued as rs762299337; called by muse, mutect2
- TRPC4AP | c.2112G>A p.R704= | Silent (SNP) | VAF 14/437 reads (3%) | called by muse, mutect2
- TSEN15 | c.342C>T p.L114= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as rs948403610; called by muse, mutect2
- UBR1 | c.3294C>T p.C1098= | Silent (SNP) | VAF 54/1058 reads (5%) | catalogued as rs1233073912; called by muse, mutect2
- UBR5 | c.5385C>A p.I1795= | Silent (SNP) | VAF 25/695 reads (4%) | called by muse, mutect2
- UNC5C | c.1032C>T p.A344= | Silent (SNP) | VAF 42/458 reads (9%) | catalogued as rs1190638294; called by muse, mutect2
- WDR5 | c.375G>A p.L125= | Silent (SNP) | VAF 34/445 reads (8%) | called by muse, mutect2
- AC011525.1 | n.918T>A | RNA (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- ACSL4 | c.-300G>C | 5'UTR (SNP) | VAF 42/377 reads (11%) | called by muse, mutect2, varscan2
- AGL | c.82+1563C>T | Intron (SNP) | VAF 32/646 reads (5%) | called by muse, mutect2
- AL353804.6 | chrX:73827207 G>A | 3'Flank (SNP) | VAF 77/467 reads (16%) | called by muse, mutect2, varscan2
- ANO9 | c.1786+21G>C | Intron (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- ANTXR1 | c.802+69C>A | Intron (SNP) | VAF 66/751 reads (9%) | called by muse, mutect2
- ARHGDIG | c.*31C>T | 3'UTR (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- BSCL2 | c.*38C>T | 3'UTR (SNP) | VAF 70/760 reads (9%) | catalogued as COSV99628306; called by muse, mutect2
- C7orf66 | n.96T>A | RNA (SNP) | VAF 32/610 reads (5%) | catalogued as rs1241546821; called by muse, mutect2
- CAPN8 | c.*17T>A | 3'UTR (SNP) | VAF 30/636 reads (5%) | called by muse, mutect2
- CDH2 | c.-8C>A | 5'UTR (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- COG6 | c.153+271A>T | Intron (SNP) | VAF 30/713 reads (4%) | called by muse, mutect2
- CXorf58 | c.423+18A>G | Intron (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2
- CXorf58 | c.423+19C>T | Intron (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2
- DCTN1 | c.*41C>G | 3'UTR (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- DDX41 | c.*398A>G | 3'UTR (SNP) | VAF 132/538 reads (25%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1160G>C | 3'UTR (SNP) | VAF 24/316 reads (8%) | called by muse, mutect2
- FIS1 | c.-3G>C | 5'UTR (SNP) | VAF 33/243 reads (14%) | called by muse, mutect2, varscan2
- FOXP2 | c.258+3626G>A | Intron (SNP) | VAF 50/714 reads (7%) | called by muse, mutect2
- GAS7 | c.184-16576G>C | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- GNG2 | c.-102A>T | 5'UTR (SNP) | VAF 22/510 reads (4%) | called by muse, mutect2
- GYG1 | chr3:148991536 C>A | 5'Flank (SNP) | VAF 24/918 reads (3%) | catalogued as rs966626416; called by muse, mutect2
- HOXA7 | chr7:27152876 C>A | 3'Flank (SNP) | VAF 155/799 reads (19%) | called by muse, mutect2, varscan2
- IL1B | c.597+32C>A | Intron (SNP) | VAF 33/906 reads (4%) | called by muse, mutect2
- ITK | c.-13C>G | 5'UTR (SNP) | VAF 20/757 reads (3%) | called by muse, mutect2
- LEKR1 | c.*1011G>C | 3'UTR (SNP) | VAF 28/372 reads (8%) | catalogued as COSV62964801; called by muse, mutect2
- LEKR1 | c.*1212G>C | 3'UTR (SNP) | VAF 56/468 reads (12%) | called by muse, mutect2, varscan2
- LINC00602 | n.784G>T | RNA (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- LINC01804 | n.355G>A | RNA (SNP) | VAF 30/316 reads (9%) | catalogued as rs1558487181; called by muse, mutect2
- LMAN1 | c.1221-17G>C | Intron (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- LRIT3 | c.590-2430A>G | Intron (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- LRRC75A | c.376-54G>C | Intron (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- MAP4K4 | c.1867-1105A>T | Intron (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- MIR1270 | chr19:20397456 G>C | 3'Flank (SNP) | VAF 35/735 reads (5%) | called by muse, mutect2
- MSRB3 | c.98-18211G>C | Intron (SNP) | VAF 72/1378 reads (5%) | called by muse, mutect2
- NCAN | c.-35C>A | 5'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- NME7 | c.-14G>A | 5'UTR (SNP) | VAF 41/1010 reads (4%) | called by muse, mutect2
- NOS3 | c.2985-526G>C | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- NRIP3 | c.711-35G>T | Intron (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- NUP155 | c.-28C>T | 5'UTR (SNP) | VAF 36/636 reads (6%) | called by muse, mutect2
- OPALIN | c.-42del | 5'UTR (DEL) | VAF 62/446 reads (14%) | called by mutect2, pindel, varscan2
- PCLO | c.13654+11209C>G | Intron (SNP) | VAF 36/610 reads (6%) | catalogued as rs1046367210; called by muse, mutect2
- PDCD5 | c.258+106C>G | Intron (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- PDZD11 | c.-13-35A>T | Intron (SNP) | VAF 20/468 reads (4%) | called by muse, mutect2
- PEX19 | c.*115C>G | 3'UTR (SNP) | VAF 13/390 reads (3%) | called by muse, mutect2
- PIK3CD | c.-138+2635C>T | Intron (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- PKHD1L1 | c.9327+468T>G | Intron (SNP) | VAF 62/399 reads (16%) | called by muse, varscan2
- PPP1R13B | c.*137G>A | 3'UTR (SNP) | VAF 24/598 reads (4%) | called by muse, mutect2
- RPS20 | c.3+80G>C | Intron (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- RSRC1 | c.320+8109C>T | Intron (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- S1PR1 | c.-1C>A | 5'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SCN1A | c.4285-27G>C | Intron (SNP) | VAF 56/408 reads (14%) | called by muse, mutect2, varscan2
- SGPL1 | c.-1G>A | 5'UTR (SNP) | VAF 67/707 reads (9%) | called by muse, mutect2, varscan2
- SLC9A9 | c.*48G>A | 3'UTR (SNP) | VAF 18/382 reads (5%) | catalogued as rs1041776440; called by muse, mutect2
- SNORD116-17 | chr15:25088027 G>C | 3'Flank (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- SRRM3 | c.1733+455G>A | Intron (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- ST3GAL6 | c.336-2651A>G | Intron (SNP) | VAF 29/533 reads (5%) | called by muse, mutect2
- STAR | c.650+32C>G | Intron (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- TAZ | c.542-31C>G | Intron (SNP) | VAF 115/883 reads (13%) | called by muse, mutect2, varscan2
- TRHDE | chr12:72272002 C>T | 5'Flank (SNP) | VAF 479/1351 reads (35%) | called by muse, mutect2, varscan2
- TUBB3 | c.-46C>T | 5'UTR (SNP) | VAF 16/240 reads (7%) | catalogued as rs891008533; called by muse, mutect2
- TULP2 | c.1447+12G>A | Intron (SNP) | VAF 23/406 reads (6%) | called by muse, mutect2
- UBE2DNL | n.97C>T | RNA (SNP) | VAF 15/342 reads (4%) | catalogued as rs1215133322; called by muse, mutect2
- WDR83OS | c.255-14C>G | Intron (SNP) | VAF 10/213 reads (5%) | catalogued as rs1050506913; called by muse, mutect2
- WTAP | c.-455C>G | 5'UTR (SNP) | VAF 15/303 reads (5%) | called by muse, mutect2
- XIAP | c.*1737A>C | 3'UTR (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- Y_RNA | chr7:75515769 C>G | 5'Flank (SNP) | VAF 78/433 reads (18%) | catalogued as rs374074643; called by muse, mutect2, varscan2
- ZFPM2 | n.262A>G | RNA (SNP) | VAF 29/545 reads (5%) | catalogued as rs1354465479; called by muse, mutect2
- ZNF133 | c.217+3866G>T | Intron (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- ZNF134 | c.-259G>C | 5'UTR (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- ZNF99 | c.*84A>G | 3'UTR (SNP) | VAF 17/462 reads (4%) | called by muse, mutect2
